Gene-level copy-number profile of tumor specimen TCGA-HC-7736-01A from TCGA case TCGA-HC-7736, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,703 days).
Specimen TCGA-HC-7736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.33cdfda5-62b4-4f2a-a8dc-4c46e3f8cc44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-7736-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/668bec79-5ec3-4035-a0c6-243d5d7f10cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 11,833; copy number 2: 46,642; copy number 3: 1,101; copy number 4: 128; copy number 5: 16; copy number 6: 9; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-7736-01A-11D-2112-01): tumor purity 0.6, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:217,426,992–217,871,696, 3 genes (within-gene range 0–1): GPATCH2, SPATA17, SPATA17-AS1.
- chr3:151,733,916–153,980,186, 28 genes (within-gene range 0–1): AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, AC092924.2, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA.
- chr9:16,726,814–16,775,845, 2 genes: BNC2-AS1, LSM1P1.
- chr11:5,551,662–5,644,398, 8 genes: OR52H2P, OR52B5P, OR52T1P, HNRNPA1P53, OR52B6, TRIM6, TRIM6-TRIM34, TRIM34.
- chr11:90,071,136–90,192,894, 8 genes: AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.9, AP000648.1, AP000648.3, NAALAD2.
- chr11:98,130,239–98,131,198, 1 gene: AP001317.1.
- chr12:128,793,194–129,016,663, 6 genes: SLC15A4, AC108704.2, AC108704.1, GLT1D1, AC069262.1, NLRP9P1.
- chr13:22,589,699–22,924,602, 11 genes: AL512484.1, FTH1P7, DDX39AP1, SNORD36, RPL7AP73, IPMKP1, RFESDP1, LINC00621, BASP1P1, NUS1P2, AL157931.1.
- chr16:63,730,205–63,936,906, 2 genes (within-gene range 0–1): LINC02165, AC092337.1.
- chr16:86,764,298–86,961,268, 3 genes: AC130467.1, AC093519.2, AC093519.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,143,367–10,295,579, 10 genes, copy number 5: AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–77,433,388, 4 genes, copy number 7 (within-gene range 2–7): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr6:39,934,595–40,000,527, 2 genes, copy number 5 (within-gene range 2–5): TUBBP9, FO393411.1.
- chr7:63,011,463–63,011,569, 1 gene, copy number 5: RNU6-417P.
- chr8:46,822,174–46,907,309, 7 genes, copy number 6 (within-gene range 2–6): LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr8:128,220,504–128,564,679, 3 genes, copy number 5: RN7SKP226, AC100822.1, LINC00824.
- chr9:109,760,360–109,772,043, 1 gene, copy number 6 (within-gene range 2–6): AL158829.1.
- chr19:8,848,844–8,981,342, 1 gene, copy number 6 (within-gene range 2–6): MUC16.

Autosomal genes at a single copy (total copy number 1): 9,459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
